Somatic mutation profile of tumor specimen TCGA-64-5774-01A (aliquot TCGA-64-5774-01A-01D-1625-08) from TCGA case TCGA-64-5774, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Main bronchus; AJCC pathologic stage: Stage IB; Age at diagnosis: 60.4 years (22,059 days).
Specimen TCGA-64-5774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a98ddc58-96ef-4278-bf6d-43521099a344.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-5774-10A (Blood Derived Normal), aliquot TCGA-64-5774-10A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/268d3f56-e3e4-446b-a783-1af4e5061661

The open-access MAF lists 152 somatic variants for this specimen: 113 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 36, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 3, Intron 1, Splice Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/26 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.842dup p.L282Afs*3 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | catalogued as rs121913321; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA3 | c.2952G>T p.E984D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.034); catalogued as COSV57060533; called by muse, mutect2, varscan2
- ABI3 | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV56801612; called by muse, mutect2, varscan2
- ACER1 | c.762C>A p.Y254* | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as COSV56834559, COSV56837114; called by muse, mutect2, varscan2
- ACOT2 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV53151708; called by muse, mutect2, varscan2
- ADAMTS5 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.206); catalogued as COSV53185899; called by muse, mutect2, varscan2
- AMBRA1 | c.3699G>T p.W1233C (on ENST00000458649 / NM_001367468.1; = p.W1143C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.253); catalogued as COSV54051792, COSV54063242; called by muse, mutect2, varscan2
- ARHGAP21 | c.5062C>T p.R1688W | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs772625929, COSV57611627; called by muse, mutect2, varscan2
- ATM | c.3586A>T p.K1196* | Nonsense Mutation (SNP) | VAF 58/79 reads (73%) | catalogued as COSV53777991; called by muse, mutect2, varscan2
- BECN1 | c.1313G>T p.W438L | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162060; called by muse, mutect2, varscan2
- C6orf89 | c.529G>C p.E177Q (on ENST00000373685; = p.E184Q on NM_152734.4) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100769689, COSV100769757; called by muse, mutect2, varscan2
- CCNE1 | c.1154G>C p.R385T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.4); catalogued as COSV99388220; called by muse, mutect2, varscan2
- CCNE1 | c.1155G>T p.R385S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.328); catalogued as COSV99388222; called by muse, mutect2, varscan2
- CDH10 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV52599728; called by muse, mutect2, varscan2
- CEMIP2 | c.2123C>A p.P708Q | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs868353463, COSV65489808; called by muse, mutect2, varscan2
- CHRNA1 | c.372C>G p.H124Q (on ENST00000261007 / NM_001039523.3; = p.H99Q on NM_000079.4) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV53685516; called by muse, mutect2, varscan2
- COL5A2 | c.1834G>T p.G612W | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66415841; called by muse, mutect2, varscan2
- CSMD1 | c.4332C>A p.D1444E (on ENST00000520002; = p.D1443E on NM_033225.6) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV59389925; called by muse, mutect2, varscan2
- CUBN | c.5515A>G p.S1839G | Missense Mutation (SNP) | VAF 132/176 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV64728207; called by muse, mutect2, varscan2
- DDX1 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV51841446, COSV51843833; called by muse, mutect2, varscan2
- DLG2 | c.2360C>A p.A787D | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54688316; called by muse, mutect2, varscan2
- DLGAP2 | c.254C>A p.S85Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs777119247, COSV70104135; called by muse, mutect2
- DLGAP2 | c.813C>A p.H271Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.46); catalogued as rs770219072, COSV70093878, COSV70104137; called by muse, mutect2, varscan2
- DLGAP2 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV101421957, COSV70102184; called by muse, mutect2, varscan2
- DNAH11 | c.2125T>C p.F709L | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs776494209, COSV60984273; called by muse, mutect2, varscan2
- DNAH5 | c.12705+1G>T p.X4235_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as rs779993876, COSV54203782; called by muse, mutect2, varscan2
- DNAH5 | c.12705G>T p.K4235N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as BM1246146, COSV54251412, COSV99446248; called by muse, mutect2, varscan2
- DNMT3A | c.1481G>C p.C494S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1240736156, COSV53052239, COSV99260306; called by muse, mutect2, varscan2
- DPY19L2 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 82/141 reads (58%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.293); catalogued as COSV60546180; called by muse, mutect2, varscan2
- EDIL3 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56923081; called by muse, mutect2, varscan2
- EMSY | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58265583; called by muse, mutect2, varscan2
- EP300 | c.4453G>T p.D1485Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327138; called by muse, mutect2, varscan2
- EPHA5 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV56632749, COSV56676910; called by muse, mutect2, varscan2
- FAF2 | c.703A>G p.M235V | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV56133355; called by muse, mutect2, varscan2
- FAM204A | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs148686616; called by muse, mutect2, varscan2
- GABRG1 | c.65G>C p.R22T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.108); catalogued as COSV54950622, COSV54962485; called by muse, mutect2, varscan2
- GALNT5 | c.1716G>T p.R572S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52041614; called by muse, mutect2, varscan2
- GRIK2 | c.2632A>T p.K878* | Nonsense Mutation (SNP) | VAF 29/46 reads (63%) | catalogued as rs1310886013, COSV59776017; called by muse, mutect2, varscan2
- HMCN1 | c.4927G>T p.G1643C | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV54945004; called by muse, mutect2, varscan2
- HTR1F | c.531C>A p.D177E | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV60391398; called by muse, mutect2, varscan2
- IRF8 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV51900794; called by muse, mutect2, varscan2
- KCNH1 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.833); catalogued as COSV55106492; called by muse, mutect2, varscan2
- KIF1A | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100240094; called by muse, mutect2, varscan2
- KMT2D | c.15754G>T p.D5252Y | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56491121; called by muse, mutect2, varscan2
- KRT12 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs779768900, COSV52432616; called by muse, mutect2, varscan2
- LIPH | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56186572; called by muse, mutect2, varscan2
- LRRC1 | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV63830981; called by muse, mutect2, varscan2
- LRRTM4 | c.1312A>G p.M438V | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs746655515, COSV69142797; called by muse, mutect2, varscan2
- MAMLD1 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.69); PolyPhen benign (0.022); catalogued as rs781882571, COSV53381307, COSV99475428; called by muse, mutect2, varscan2
- MMP13 | c.1232T>C p.I411T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52825854; called by muse, mutect2, varscan2
- MTR | c.3395G>T p.R1132L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM159498, COSV63966468; called by muse, mutect2, varscan2
- MUC17 | c.8297C>G p.S2766C | Missense Mutation (SNP) | VAF 163/308 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV60283834, COSV60305361; called by muse, mutect2, varscan2
- MUC7 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.235); catalogued as COSV59220292; called by muse, mutect2, varscan2
- MYBL2 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53834056; called by muse, mutect2, varscan2
- MYH2 | c.5471G>A p.R1824K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV55449515; called by muse, mutect2, varscan2
- MYH7 | c.2286G>C p.K762N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62524408; called by muse, mutect2, varscan2
- MYO18B | c.1241A>T p.K414M | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV59150154; called by muse, mutect2, varscan2
- MYOM3 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.76); PolyPhen benign (0.154); catalogued as rs374208248, COSV58401658; called by muse, mutect2, varscan2
- MYRF | c.358C>A p.P120T (on ENST00000278836 / NM_001127392.3; = p.P111T on NM_013279.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs771248547, COSV53894504; called by muse, mutect2, varscan2
- NEFL | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs121913663, CM092125, COSV99647867; ClinVar: uncertain significance; called by muse, varscan2
- NRXN1 | c.1660C>A p.L554M | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); catalogued as COSV58496989; called by muse, mutect2, varscan2
- NTN4 | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs373667972; called by muse, mutect2, varscan2
- OBSCN | c.19552G>T p.A6518S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV63548025; called by muse, mutect2, varscan2
- OR2C1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs147461021, COSV59241320; called by muse, mutect2, varscan2
- OR4X2 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56585313; called by muse, mutect2, varscan2
- OR6N2 | c.423T>G p.C141W | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1001639693, COSV59413303; called by muse, mutect2, varscan2
- OR8G5 | c.718A>T p.T240S | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100422275; called by muse, varscan2
- PARP9 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64452114; called by muse, mutect2
- PCDHA2 | c.1735G>T p.E579* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | catalogued as COSV100974075, COSV65371524; called by muse, mutect2, varscan2
- PCDHB12 | c.420A>T p.L140F | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53401430; called by muse, mutect2, varscan2
- PCDHB8 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99176242; called by muse, mutect2, varscan2
- PCDHGB2 | c.2266G>T p.V756F | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); catalogued as COSV54042252; called by muse, mutect2, varscan2
- PCSK6 | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1459787573, COSV61861685; called by muse, mutect2, varscan2
- PDHA2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs754242583, COSV54780630; called by muse, mutect2, varscan2
- PDIA6 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs138012463; called by muse, mutect2, varscan2
- PGM1 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 3/53 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV64301777; called by muse, mutect2
- PIK3R5 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.089); catalogued as COSV52659146; called by muse, mutect2, varscan2
- PKHD1L1 | c.4387A>T p.T1463S | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV101006569, COSV65754313; called by muse, mutect2, varscan2
- PLEKHG4 | c.3250G>T p.A1084S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58575498; called by muse, mutect2, varscan2
- PLXNA4 | c.1840T>C p.S614P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100323050; called by muse, varscan2
- RASAL1 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.184); catalogued as COSV55660115; called by muse, mutect2, varscan2
- RIPK4 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60185778; called by muse, mutect2, varscan2
- RTN4IP1 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.77); PolyPhen benign (0.006); catalogued as COSV64806614; called by muse, mutect2, varscan2
- RXFP4 | c.509C>A p.A170D | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.515); catalogued as COSV58151761; called by muse, mutect2, varscan2
- SEC23A | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs148560912, COSV56973037; called by muse, mutect2, varscan2
- SEMA6A | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56714006, COSV56715296; called by muse, mutect2, varscan2
- SLC12A5 | c.3309C>A p.N1103K (on ENST00000454036 / NM_001134771.2; = p.N1080K on NM_020708.5) | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV51647694; called by muse, mutect2, varscan2
- SLC6A7 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.359); catalogued as COSV100046039; called by muse, mutect2, varscan2
- SPNS3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV61072470; called by muse, mutect2, varscan2
- TENT2 | c.1087G>T p.A363S | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV57139518; called by muse, mutect2, varscan2
- TMEM225 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV66693216; called by muse, mutect2, varscan2
- TMEM255B | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as COSV64711484, COSV64715085; called by muse, mutect2, varscan2
- TMEM81 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52707044; called by muse, mutect2, varscan2
- TMOD3 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1566866745, COSV57946615; called by muse, mutect2, varscan2
- TRIM3 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV61985831, COSV61985949; called by muse, mutect2, varscan2
- TRIM49 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV61672104; called by muse, mutect2, varscan2
- TSHZ3 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV53683875, COSV99552902; called by muse, mutect2, varscan2
- WNT9B | c.295A>T p.N99Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51520246; called by muse, mutect2
- Z83844.2 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV60929896; called by muse, mutect2, varscan2
- ZEB1 | c.3181G>T p.G1061W | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV58055939; called by muse, mutect2, varscan2
- ZMYM1 | c.650G>T p.C217F | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.687); catalogued as COSV63253969; called by muse, mutect2, varscan2
- ZNF671 | c.674del p.G225Afs*5 | Frame Shift Del (DEL) | VAF 9/69 reads (13%) | catalogued as COSV58051574; called by mutect2, pindel*
- ZNF831 | c.3695C>A p.T1232N | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as COSV100925862; called by muse, mutect2
- ZPLD1 | c.981G>T p.W327C (on ENST00000466937 / NM_001329788.1; = p.W343C on NM_175056.2) | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV60356302; called by muse, mutect2, varscan2
- CACNA1A | c.1922del p.N641Ifs*18 | Frame Shift Del (DEL) | VAF 43/68 reads (63%) | called by mutect2, pindel, varscan2
- DEFB115 | c.136dup p.R46Kfs*8 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- DGKB | c.514del p.S172Rfs*3 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- KCNK10 | c.1398del p.E467Rfs*38 | Frame Shift Del (DEL) | VAF 53/170 reads (31%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1483G>T p.A495S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.228); called by muse, mutect2
- PITPNM3 | c.2733_2735delinsTT p.A912Cfs*183 | Frame Shift Del (DEL) | VAF 16/34 reads (47%) | called by pindel, varscan2*
- TRAPPC11 | c.1447_1450dup p.R484Lfs*4 | Frame Shift Ins (INS) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- VGF | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ABCC11 | c.609G>T p.V203= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62322867, COSV62326182; called by muse, mutect2, varscan2
- ADAM19 | c.315C>G p.T105= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV57440266; called by muse, mutect2, varscan2
- ADGRG4 | c.3036T>C p.T1012= | Silent (SNP) | VAF 114/134 reads (85%) | catalogued as COSV54967652; called by muse, mutect2, varscan2
- ATP9A | c.1806A>G p.A602= | Silent (SNP) | VAF 80/376 reads (21%) | catalogued as COSV58772586; called by muse, mutect2, varscan2
- C16orf71 | c.699G>A p.A233= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs772927921, COSV54795120; called by muse, mutect2, varscan2
- CAPN10 | c.1584G>T p.T528= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV54380034; called by muse, mutect2, varscan2
- CCDC185 | c.201C>A p.T67= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV64822038; called by muse, mutect2
- CELF3 | c.1369C>A p.R457= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV51881646, COSV51886082, COSV99310441; called by muse, mutect2, varscan2
- CEP70 | c.1419C>T p.F473= | Silent (SNP) | VAF 101/240 reads (42%) | catalogued as COSV53878665; called by muse, mutect2, varscan2
- DDI1 | c.154C>A p.R52= | Silent (SNP) | VAF 64/90 reads (71%) | catalogued as COSV56395306; called by muse, mutect2, varscan2
- DEFB106B | c.183G>A p.G61= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as COSV100128881; called by muse, mutect2, varscan2
- DLG2 | c.2595C>A p.P865= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV54688290; called by muse, mutect2, varscan2
- DNMT3A | c.1482C>T p.C494= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99260295; called by muse, mutect2, varscan2
- FAM131B | c.318G>C p.V106= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV68127049; called by muse, mutect2, varscan2
- FAM47A | c.234C>A p.L78= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV60495290, COSV60500077; called by muse, mutect2, varscan2
- FBXO10 | c.1254G>A p.K418= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV52835930; called by muse, mutect2, varscan2
- GAS2L2 | c.1725C>A p.S575= | Silent (SNP) | VAF 26/111 reads (23%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.397C>T p.L133= | Silent (SNP) | VAF 96/182 reads (53%) | catalogued as COSV58488131, COSV58491857; called by muse, mutect2, varscan2
- LAMA5 | c.1497A>T p.A499= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV53373506; called by muse, mutect2, varscan2
- LRRC32 | c.375C>T p.R125= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as rs771338935, COSV52635697; called by muse, mutect2, varscan2
- MAP3K19 | c.420C>A p.P140= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV59642591, COSV59642621; called by muse, mutect2, varscan2
- MYLK2 | c.345G>A p.Q115= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV65660063; called by muse, mutect2, varscan2
- NEMF | c.1819C>A p.R607= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as COSV53595701; called by muse, mutect2, varscan2
- NLRP8 | c.1335G>A p.K445= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV52583464, COSV52594593; called by muse, mutect2, varscan2
- NRG1 | c.141G>T p.S47= | Silent (SNP) | VAF 60/97 reads (62%) | catalogued as COSV99827943; called by muse, mutect2, varscan2
- OR56A3 | c.120C>A p.L40= | Silent (SNP) | VAF 71/91 reads (78%) | catalogued as COSV61569800, COSV61570156; called by muse, mutect2, varscan2
- OR8J3 | c.747G>T p.T249= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV56880098, COSV56881389; called by muse, mutect2, varscan2
- PZP | c.3870G>A p.Q1290= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV54370232; called by muse, mutect2, varscan2
- SIRPB1 | c.330C>A p.I110= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as COSV53540929; called by muse, mutect2, varscan2
- SPPL2B | c.270C>A p.I90= | Silent (SNP) | VAF 44/56 reads (79%) | catalogued as COSV101194600; called by muse, mutect2, varscan2
- SPTA1 | c.5328A>T p.A1776= | Silent (SNP) | VAF 96/231 reads (42%) | catalogued as COSV63760284; called by muse, mutect2, varscan2
- TRDV1 | c.60G>T p.V20= | Silent (SNP) | VAF 94/235 reads (40%) | called by muse, mutect2, varscan2
- TRIM3 | c.657G>C p.L219= | Silent (SNP) | VAF 58/87 reads (67%) | catalogued as COSV100624279; called by muse, mutect2, varscan2
- WASHC5 | c.1033C>T p.L345= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV59200921; called by muse, mutect2, varscan2
- ZNF33A | c.606T>C p.H202= (on ENST00000458705 / NM_006974.3; = p.H203= on NM_006954.2) | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV56728081; called by muse, mutect2, varscan2
- ZNF521 | c.3366G>A p.E1122= | Silent (SNP) | VAF 24/41 reads (59%) | catalogued as COSV64132287; called by muse, mutect2, varscan2
- FTCD | c.*8C>A | 3'UTR (SNP) | VAF 17/21 reads (81%) | catalogued as rs759470658, COSV99384743; called by muse, mutect2, varscan2
- LY9 | c.454+1756G>A | Intron (SNP) | VAF 123/254 reads (48%) | catalogued as rs369757789, COSV54433250; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43304749 C>A | 3'Flank (SNP) | VAF 46/91 reads (51%) | called by muse, mutect2, varscan2
